Somatic mutation profile of tumor specimen TCGA-CK-5912-01A (aliquot TCGA-CK-5912-01A-11D-1650-10) from TCGA case TCGA-CK-5912, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Ascending colon; AJCC pathologic stage: Stage I; Age at diagnosis: 82.0 years (29,938 days).
Specimen TCGA-CK-5912-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3dd81bcc-c8e6-4f5b-8ab5-2c495acda5ad.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CK-5912-10A (Blood Derived Normal), aliquot TCGA-CK-5912-10A-01D-1650-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/65280f9d-9c1b-4254-bd06-69c599d3a345

The open-access MAF lists 64 somatic variants for this specimen: 48 protein-altering or splice-affecting, 15 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 40, Silent 15, Frame Shift Del 3, Frame Shift Ins 2, Nonsense Mutation 1, In Frame Del 1, In Frame Ins 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA13 | c.7972G>C p.A2658P | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.809); catalogued as COSV71290882; called by muse, mutect2, varscan2
- ABHD5 | c.680G>A p.R227H | Missense Mutation (SNP) | VAF 170/493 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.934); catalogued as rs143489624; called by muse, mutect2, varscan2
- AC005324.2 | c.121G>A p.E41K | Missense Mutation (SNP) | VAF 38/46 reads (83%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.022); catalogued as COSV60887314; called by muse, mutect2, varscan2
- APOBEC3B | c.916C>T p.R306C | Missense Mutation (SNP) | VAF 74/247 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.014); catalogued as rs747498277, COSV59840889; called by muse, mutect2, varscan2
- ARFGEF1 | c.5279A>G p.E1760G | Missense Mutation (SNP) | VAF 79/172 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.014); catalogued as COSV51587591; called by muse, mutect2, varscan2
- ATR | c.3431G>A p.G1144D | Missense Mutation (SNP) | VAF 320/820 reads (39%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.975); catalogued as COSV63384685; called by muse, mutect2, varscan2
- CDH10 | c.383G>A p.R128H | Missense Mutation (SNP) | VAF 232/381 reads (61%) | SIFT tolerated (0.23); PolyPhen benign (0.148); catalogued as rs369925572, COSV100051837; called by muse, mutect2, varscan2
- CHD4 | c.4177C>G p.R1393G (on ENST00000357008 / NM_001363606.2; = p.R1406G on NM_001273.5) | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.994); catalogued as COSV58904895, COSV58912315; called by muse, mutect2, varscan2
- CXorf21 | c.821G>A p.R274H | Missense Mutation (SNP) | VAF 258/299 reads (86%) | SIFT tolerated (0.56); PolyPhen benign (0.007); catalogued as rs149817919, COSV66762899; called by muse, mutect2, varscan2
- DDX31 | c.973G>A p.V325I | Missense Mutation (SNP) | VAF 73/177 reads (41%) | SIFT tolerated (0.43); PolyPhen benign (0.017); catalogued as COSV60137274; called by muse, mutect2, varscan2
- DNAH3 | c.578C>A p.T193K | Missense Mutation (SNP) | VAF 266/461 reads (58%) | SIFT tolerated (0.93); PolyPhen benign (0.01); catalogued as COSV54519683, COSV99766737; called by muse, mutect2, varscan2
- DUSP22 | c.80G>A p.S27N | Missense Mutation (SNP) | VAF 119/288 reads (41%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as rs150029869; called by mutect2, varscan2
- GALNT18 | c.11C>A p.T4N | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.133); catalogued as COSV57152371; called by muse, mutect2, varscan2
- IPO8 | c.158G>A p.R53Q | Missense Mutation (SNP) | VAF 197/367 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs774771126, COSV56243231; called by muse, mutect2, varscan2
- KIAA1109 | c.12575C>G p.T4192S | Missense Mutation (SNP) | VAF 37/67 reads (55%) | SIFT tolerated (0.99); PolyPhen benign (0.001); catalogued as COSV52681309; called by muse, mutect2, varscan2
- LACTB2 | c.673C>T p.L225F | Missense Mutation (SNP) | VAF 307/722 reads (43%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.646); catalogued as COSV52567063; called by muse, mutect2, varscan2
- LAMC3 | c.854C>T p.A285V | Missense Mutation (SNP) | VAF 42/84 reads (50%) | SIFT tolerated (0.53); PolyPhen benign (0.043); catalogued as rs750805884, COSV63089004; called by muse, mutect2, varscan2
- LINGO2 | c.970C>T p.R324C | Missense Mutation (SNP) | VAF 34/76 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.217); catalogued as rs202210200, COSV58059589; called by muse, mutect2, varscan2
- MASP1 | c.380G>A p.R127H | Missense Mutation (SNP) | VAF 125/284 reads (44%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.643); catalogued as rs367766973; called by muse, varscan2
- MLF2 | c.520G>C p.D174H | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV52571638; called by muse, mutect2, varscan2
- NLGN4Y | c.1187A>T p.D396V | Missense Mutation (SNP) | VAF 32/77 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); catalogued as COSV100196678; called by muse, mutect2, varscan2
- NXF3 | c.262G>A p.V88I | Missense Mutation (SNP) | VAF 38/325 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.024); catalogued as COSV67704320; called by muse, mutect2, varscan2
- OR2L3 | c.778C>T p.R260C | Missense Mutation (SNP) | VAF 264/328 reads (80%) | SIFT tolerated (0.09); PolyPhen benign (0.033); catalogued as rs765931236, COSV63455451; called by muse, varscan2
- PCDHGA6 | c.1120C>T p.R374* | Nonsense Mutation (SNP) | VAF 75/95 reads (79%) | catalogued as rs1346536726, COSV53892106; called by muse, mutect2, varscan2
- POLR2A | c.5692A>G p.T1898A | Missense Mutation (SNP) | VAF 127/151 reads (84%) | SIFT tolerated (0.19); PolyPhen benign (0.388); catalogued as rs938251415; called by muse, mutect2, varscan2
- POLR3A | c.664G>A p.V222I | Missense Mutation (SNP) | VAF 27/76 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as rs1189604133, COSV100965622; called by muse, mutect2, varscan2
- PRDM9 | c.1125A>T p.K375N | Missense Mutation (SNP) | VAF 137/529 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.134); catalogued as COSV57009284; called by muse, mutect2, varscan2
- PTPRD | c.2398G>A p.V800I | Missense Mutation (SNP) | VAF 67/151 reads (44%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.721); catalogued as rs201412075, COSV61960470; called by muse, mutect2, varscan2
- RTN1 | c.1858G>A p.V620M | Missense Mutation (SNP) | VAF 33/40 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs143124571; called by muse, mutect2, varscan2
- RUNX1 | c.1237G>A p.A413T (on ENST00000344691 / NM_001001890.3; = p.A440T on NM_001754.5) | Missense Mutation (SNP) | VAF 7/11 reads (64%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100277206; called by muse, mutect2, varscan2
- SATB2 | c.1556A>G p.E519G | Missense Mutation (SNP) | VAF 144/162 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99611077; called by muse, mutect2, varscan2
- SCAF11 | c.4102G>A p.A1368T | Missense Mutation (SNP) | VAF 33/207 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs372602350; called by muse, mutect2, varscan2
- SMARCA2 | c.2348C>T p.S783L | Missense Mutation (SNP) | VAF 26/124 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs1554623112, CM149456, COSV61809611; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SYCP2 | c.2585C>A p.T862N | Missense Mutation (SNP) | VAF 268/1365 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.758); catalogued as COSV62769830; called by muse, mutect2, varscan2
- TBC1D10B | c.1660C>T p.R554W | Missense Mutation (SNP) | VAF 32/154 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs779727462, COSV59769206; called by muse, mutect2, varscan2
- TBX3 | c.1909C>T p.R637W (on ENST00000257566 / NM_016569.4; = p.R617W on NM_005996.4) | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.99); catalogued as COSV99983702; called by muse, mutect2
- TM7SF3 | c.486C>G p.I162M | Missense Mutation (SNP) | VAF 41/160 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.362); catalogued as rs1368713539, COSV100544765; called by muse, mutect2, varscan2
- TUBGCP2 | c.2054G>A p.R685Q | Missense Mutation (SNP) | VAF 50/105 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs765603563, COSV53304587; called by muse, mutect2, varscan2
- UNC13C | c.3170G>A p.R1057Q | Missense Mutation (SNP) | VAF 62/175 reads (35%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.96); catalogued as rs182809015, COSV52894311; called by muse, mutect2, varscan2
- ZNF804B | c.1339C>G p.Q447E | Missense Mutation (SNP) | VAF 35/155 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.122); catalogued as COSV60837107; called by muse, mutect2, varscan2
- APC | c.2506_2519del p.S836Lfs*3 | Frame Shift Del (DEL) | VAF 33/43 reads (77%) | called by pindel, varscan2
- EDEM1 | c.818del p.P273Lfs*15 | Frame Shift Del (DEL) | VAF 54/150 reads (36%) | called by mutect2, pindel*, varscan2
- H1-4 | c.622_636del p.A208_K212del | In Frame Del (DEL) | VAF 31/74 reads (42%) | called by mutect2, pindel, varscan2
- IGHV1OR21-1 | c.296A>T p.Y99F | Missense Mutation (SNP) | VAF 102/448 reads (23%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.579); called by muse, mutect2, varscan2
- KCNU1 | c.280_282dup p.L95dup | In Frame Ins (INS) | VAF 23/163 reads (14%) | called by mutect2, pindel, varscan2
- LYST | c.1008dup p.V337Sfs*4 | Frame Shift Ins (INS) | VAF 10/101 reads (10%) | called by mutect2, pindel, varscan2
- RPLP1 | c.339del p.F113Lfs*7 | Frame Shift Del (DEL) | VAF 22/50 reads (44%) | called by mutect2, pindel, varscan2
- USP9X | c.7128dup p.K2377* | Frame Shift Ins (INS) | VAF 279/421 reads (66%) | called by mutect2, pindel, varscan2
- ATP11C | c.3066G>A p.T1022= | Silent (SNP) | VAF 287/328 reads (88%) | catalogued as rs1172482306, COSV59568004; called by muse, mutect2, varscan2
- CACNG8 | c.183C>T p.G61= | Silent (SNP) | VAF 20/24 reads (83%) | catalogued as COSV54415723, COSV54416438; called by muse, mutect2, varscan2
- FBXL7 | c.1146C>T p.N382= | Silent (SNP) | VAF 10/95 reads (11%) | catalogued as rs746695934, COSV61640788; called by muse, mutect2, varscan2
- FRMPD1 | c.2517G>A p.R839= | Silent (SNP) | VAF 44/87 reads (51%) | catalogued as COSV66698942, COSV66701116; called by muse, mutect2, varscan2
- GLB1L2 | c.516C>T p.D172= | Silent (SNP) | VAF 36/93 reads (39%) | catalogued as COSV60279412; called by muse, mutect2, varscan2
- GPR158 | c.2622G>A p.P874= | Silent (SNP) | VAF 53/124 reads (43%) | catalogued as rs567691480, COSV100894383, COSV66274913; called by muse, mutect2, varscan2
- LIMD2 | c.60C>T p.G20= | Silent (SNP) | VAF 20/34 reads (59%) | catalogued as rs1333782887, COSV99368524; called by muse, mutect2, varscan2
- LNX1 | c.873G>A p.V291= (on ENST00000263925 / NM_001126328.3; = p.V195= on NM_032622.2) | Silent (SNP) | VAF 48/140 reads (34%) | catalogued as rs963143390, COSV55788211; called by muse, mutect2, varscan2
- MEGF10 | c.1893C>T p.C631= | Silent (SNP) | VAF 52/69 reads (75%) | catalogued as rs777777875, COSV57252441; called by muse, mutect2, varscan2
- OPCML | c.927C>T p.I309= | Silent (SNP) | VAF 9/122 reads (7%) | catalogued as rs1380968532, COSV100100192; called by muse, mutect2
- PCDH9 | c.126C>T p.N42= | Silent (SNP) | VAF 28/297 reads (9%) | catalogued as COSV60527726; called by muse, mutect2
- RIPOR3 | c.1642C>T p.L548= | Silent (SNP) | VAF 7/34 reads (21%) | catalogued as COSV50393601; called by muse, mutect2, varscan2
- RUNX1T1 | c.1194C>T p.D398= (on ENST00000265814 / NM_001198628.1; = p.D371= on NM_004349.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 38/198 reads (19%) | catalogued as rs201685328, COSV56140558, COSV56155824; called by muse, varscan2
- SLC1A3 | c.1269C>T p.F423= | Silent (SNP) | VAF 32/205 reads (16%) | catalogued as rs758802146, COSV54317468; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SYNJ1 | c.2016G>A p.L672= | Silent (SNP) | VAF 29/135 reads (21%) | catalogued as rs1421466293, COSV59151391; called by muse, mutect2, varscan2
- KRTAP5-2 | c.*2G>A | 3'UTR (SNP) | VAF 8/132 reads (6%) | catalogued as rs747280175, COSV101295074; called by muse, mutect2
